Gene-level copy-number profile of tumor specimen TCGA-BI-A0VR-01A from TCGA case TCGA-BI-A0VR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G3; Age at diagnosis: 53.3 years (19,473 days).
Specimen TCGA-BI-A0VR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.6a0edb0b-76ed-4652-b265-1c7593a82a6b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BI-A0VR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/156e78c0-7e0a-4b6b-94a6-dcca015f25e2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 212; copy number 3: 5,795; copy number 4: 35,072; copy number 5: 12,036; copy number 6: 4,492; copy number 7: 150; copy number 9: 188; copy number 10: 1,869.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BI-A0VR-01A-11D-A10T-01): tumor purity 0.32, ploidy 2.21, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,057 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:91,356,755–198,222,513, 1,802 genes, copy number 10 (broad region; genes not listed).
- chr14:22,040,594–22,506,702, 67 genes, copy number 10 (broad region; genes not listed).
- chr20:31,274,170–36,030,700, 188 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
